Somatic mutation profile of tumor specimen TCGA-P7-A5NX-01A (aliquot TCGA-P7-A5NX-01A-11D-A35D-08) from TCGA case TCGA-P7-A5NX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 78.0 years (28,497 days).
Specimen TCGA-P7-A5NX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ab3cd26-6d59-4833-8696-e0a4df2c6fd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P7-A5NX-10A (Blood Derived Normal), aliquot TCGA-P7-A5NX-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97e1ec42-ec58-44fb-8125-0b6b49f43b9e

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FMN2 | c.2132T>A p.L711H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.19); catalogued as COSV60437620; called by muse, mutect2, varscan2
- TRIML1 | c.518C>A p.T173N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1169207641; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2443G>C p.D815H | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV51957325; called by muse, mutect2
- ADAMTS20 | c.2012A>T p.D671V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- AGTPBP1 | c.1376C>T p.P459L (on ENST00000357081 / NM_001330701.2; = p.P419L on NM_015239.2) | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANAPC7 | c.248A>C p.H83P | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- GATAD1 | c.541A>G p.K181E | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HRC | c.1801T>C p.S601P | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- MYO5B | c.1454G>C p.W485S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDF2 | c.629A>C p.E210A | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- STAG2 | c.2814del p.F938Lfs*11 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | called by pindel, varscan2
- TENM3 | c.149T>A p.F50Y | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.95); called by muse, mutect2
- TFAP2D | c.731T>G p.L244R | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF496 | c.286C>A p.R96= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV54176170; called by mutect2, varscan2
